Surgical pathology report (de-identified scan), TCGA case TCGA-DO-A2HM, project TCGA-THCA (Thyroid Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-DO-A2HM-01B (Primary Tumor).

[page 1 of 5]
Case:
Collected:

Final Pathologic Diagnosis

A) LEFT LEVEL 3 LYMPH NODE (DISSECTION):

Final Pathologic Diagnosis

- Metastatic papillary thyroid carcinoma (2/4).

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS C73.9

fw
6/14/11

B) LEFT HEMITHYROID (THYROIDECTOMY):

- Papillary thyroid carcinoma (see synoptic report) 1.8 cm with infiltrative pattern.

- Uninvolved unremarkable parathyroid gland identified.

C) RIGHT HEMITHYROID (THYROIDECTOMY):

- Benign thyroid gland.

D) LEFT NECK LYMPH NODES LEVELS 2-4 (DISSECTION):

- Metastatic papillary carcinoma in one level 2 lymph node (1/1).

- No lymph nodes identified in level 3 and 4.

NOTE: One slide of part B of this case was reviewed in conjunction with one or more attending pathologists in this department who concur with the above diagnosis.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

ID
Electronic Signature
Verified:

Resident:

Synoptic Report

B: THYROID RESECTION - MCGHI

PROCEDURE:

Total thyroidectomy with left neck dissection

RECEIVED:

Fresh

SPECIMEN INTEGRITY:

[page 2 of 5]
Intact
SPECIMEN SIZE:
Right lobe: 4.2 cm
Left lobe: 4 cm
SPECIMEN WEIGHT:
Specify: Right lobe=10gms and Left lobe=14gms g
TUMOR FOCALITY:
Unifocal
DOMINANT TUMOR:
TUMOR LATERALITY
Left lobe
TUMOR SIZE
Greatest dimension: 1.8 cm
HISTOLOGIC TYPE
Papillary carcinoma
Classical
ARCHITECTURE:
Classical (papillary)
CYTOMORPHOLOGY
Classical
G1: Well differentiated
MARGINS
Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: <1 mm
(capsule)
TUMOR CAPSULE
Partially encapsulated
TUMOR CAPSULAR INVASION
Present
LYMPH-VASCULAR INVASION
Present
Focal (<4 vessels)
PERINEURAL INVASION
Not identified
EXTRATHYROIDAL EXTENSION
Not identified
PATHOLOGIC STAGING (pTNM):
TNM DESCRIPTORS
PRIMARY TUMOR (pT)
pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension limited to the thyroid
REGIONAL LYMPH NODES (pN)
pN1b: Metastases to unilateral bilateral or contralateral cervical (Levels I II<III< IV< V) or retropharyngeal or superior mediastinal lymph nodes (Level VII)
Number examined: 5

[page 3 of 5]
Number involved: 3
LYMPH NODE EXTRANODAL EXTENSION

Not identified
DISTANT METASTASIS (pM)

Not applicable
*ADDITIONAL PATHOLOGIC FINDINGS:
Parathyroid glands(s) (One parathyroid near pole 1 slide B9 left side.)

Diagnostic Comment

(Dr.

Focal nodular fasciitis-like stroma is present within tumor. No anaplastic carcinoma is seen in this area.

Special Procedures

IMMUNOHISTOCHEMICAL STAINS:

Stains performed at
Representative tissue present in all sections examined.
Positive and negative controls react appropriately.
Interpreted by: Dr.

Performed on block(s): B5

HBME: Positive within tumor cells.

This test was developed and its performance characteristics determined by _____ It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing._

Surg Internal Review

CPT: 88307 x 4 88331 88333 88342

Intraoperative Diagnosis

(Dr.

FS A1: Level 3 lymph node: Papillary carcinoma of the thyroid involving lymph node.

Clinical History

year old white male.

[page 4 of 5]
Pre/Post-operative Diagnosis

Thyroid cancer.

Gross Anatomic Description

(Dictated by Dr. _____ on _____ at _____ Reviewed by Dr. _____)

Gross Anatomic Description

Specimens received in four containers.

Specimen A: Designated left level 3 lymph node is received fresh for intraoperative consultation and frozen section diagnosis on

_____ labeled with the patient's name and left level 3 lymph node. Specimen consists of one piece of red/tan tissue measuring 2.2 x 1.2 x 1.1 cm. On sectioning a lymph node of 1.7 cm dimension was identified. A touch prep was performed and a representative section was frozen. A representative section was given to Tumor Bank.

Section code: A1 ♦ frozen section control entire specimen: _____ ♦ remaining entire specimen (fatty tissue).

Specimen B: Designated left hemithyroid is received fresh on

_____ labeled with the patient's name and left hemithyroid.

Specimen consists of a thyroid lobe weighing 14 g in toto and measuring 4.0 x 3.1 x 1.7 cm. The external surface is red/tan and smooth. A representative section was given for Tumor Bank. The specimen is not oriented so upper and lower pole could not be identified. On sectioning the cut surface has a white/tan lesion measuring 1.8 x 1.5 x 0.5 cm throughout the gland. The lesion does not extend beyond the inked external surface. The lesion appears to be infiltrating in the surrounding parenchyma. The uninvolved parenchyma is brown/pink and smooth. Photographs are taken.

Inking code: Blue ♦ entire external surface.

Section code: B1-B2 ♦ pole #1 cut perpendicular; B3 ♦ pole #2 cut perpendicular; B4-B11 ♦ remaining entire specimen from pole #2 ♦ pole #1.

Specimen C: Designated right hemithyroid is received in fresh on

_____ labeled with the patient's name and right hemithyroid.

Specimen consists of a thyroid lobe weighing 10 g and measuring 4.2 x 2.1 x 1.5 cm. The external surface is gray/tan and smooth. A representative section was given to Tumor Bank. On sectioning no visible lesion was identified. The current parenchyma is brown/tan and smooth.

[page 5 of 5]
Inking code: Green ♦ external surface.

Section code: C1-C2 ♦ representative sections.

Specimen D: Designated left neck dissection; levels 2-4; staples corresponding to level is received in formalin labeled with the patient's name MRN and left neck dissection; levels 2-4; staples corresponding to level. Specimen consists of a single yellow/tan fibrofatty piece of soft tissue measuring 6.5 x 3.0 x 1.0 cm. In the level 2 a single lymph node is identified measuring 0.5 x 0.3 x 0.2 cm.

Section code: D1 ♦ lymph node #1 in level 2 bisected; D2-D3 ♦ remaining portion of level 2; D4-D6 ♦ entire specimen from level 3; D7-D8 ♦ entire specimen from level 4.

Source: NCI Genomic Data Commons file d4fd69f4-77b4-4a46-8af3-7a750c36675f (TCGA-DO-A2HM.5AE4F173-F97A-43E6-904C-F179DA6FFCF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).